Somatic mutation profile of tumor specimen MP2PRT-PATISJ-TMP1-A (aliquot MP2PRT-PATISJ-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATISJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,761 days).
Specimen MP2PRT-PATISJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aff80775-d6ee-48a6-9a5c-b33c269ac47e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATISJ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATISJ-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c9bdb88-e0ab-40c1-80db-0ffd0ffb2e9d

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ASPM | c.8884C>G p.Q2962E | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54123612; called by muse, mutect2, varscan2
- ATP7A | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as rs868928182; called by muse, mutect2
- BICC1 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1201634490; called by muse, mutect2
- CEP350 | c.3356C>T p.S1119L | Missense Mutation (SNP) | VAF 110/302 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201050389, COSV62600946; called by muse, mutect2, varscan2
- CHRNA1 | c.1421G>A p.R474Q (on ENST00000261007 / NM_001039523.3; = p.R449Q on NM_000079.4) | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs757027280; called by muse, mutect2, varscan2
- CYBA | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 148/416 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs747994433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDR2 | c.2426G>C p.G809A | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV63372246; called by muse, mutect2, varscan2
- FAM135B | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 191/415 reads (46%) | catalogued as rs758974242, COSV52734447; called by muse, mutect2, varscan2
- FAM160A1 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 210/524 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.204); catalogued as rs1305521599; called by muse, mutect2, varscan2
- FANCB | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs747247621; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PACS1 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100270179; called by muse, mutect2
- RHCG | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748212663, COSV51518301; called by muse, mutect2, varscan2
- SIX1 | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 20/715 reads (3%) | catalogued as rs1349841820; called by muse, mutect2
- SPTBN5 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868228216, COSV58028192; called by muse, mutect2, varscan2
- TMEM151B | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 256/829 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381348062; called by muse, mutect2, varscan2
- UTP3 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375718549; called by muse, mutect2, varscan2
- ABCB7 | c.1973G>A p.R658K (on ENST00000373394 / NM_001271696.3; = p.R659K on NM_004299.6) | Missense Mutation (SNP) | VAF 111/378 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ABRA | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 150/439 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ARHGAP5 | c.3925C>G p.Q1309E (on ENST00000345122 / NM_001030055.2; = p.Q1308E on NM_001173.3) | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ATP10D | c.3931C>T p.L1311F | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD274 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 180/466 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPS1 | c.3307C>G p.Q1103E | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERO1A | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FZD5 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 287/692 reads (41%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GLB1L3 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 159/497 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578742 TGTCTCGCACAGTAATACATGGC>GCTTCAA | Missense Mutation (DEL) | VAF 114/165 reads (69%) | called by pindel, varscan2*
- NBEAL1 | c.7368G>C p.L2456F | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKDC | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- RNPEPL1 | c.1742-1G>A p.X581_splice | Splice Site (SNP) | VAF 174/646 reads (27%) | called by muse, mutect2, varscan2
- TSGA10 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 103/280 reads (37%) | called by muse, mutect2, varscan2
- UHRF1 | c.431_432insC p.D145Gfs*9 (on ENST00000612630 / NM_001290050.1; = p.D158Gfs*9 on NM_013282.4) | Frame Shift Ins (INS) | VAF 222/583 reads (38%) | called by mutect2, pindel, varscan2
- ZNF296 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 291/657 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF534 | c.1340G>C p.G447A (on ENST00000332323 / NM_001143939.3; = p.G434A on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/488 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ZSWIM4 | c.1178C>G p.P393R | Missense Mutation (SNP) | VAF 193/463 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIC | c.357G>A p.K119= | Silent (SNP) | VAF 230/776 reads (30%) | catalogued as rs1337284299; called by muse, mutect2, varscan2
- EIF3A | c.1704C>T p.I568= | Silent (SNP) | VAF 153/480 reads (32%) | called by muse, mutect2, varscan2
- KRT1 | c.1497G>A p.P499= | Silent (SNP) | VAF 127/404 reads (31%) | catalogued as rs145112157; called by muse, mutect2, varscan2
- PERP | c.324G>C p.L108= | Silent (SNP) | VAF 90/319 reads (28%) | catalogued as COSV69827459, COSV69827724; called by muse, mutect2, varscan2
- PLD5 | c.1602G>A p.R534= (on ENST00000442594; = p.R472= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/252 reads (31%) | catalogued as COSV59163047; called by muse, mutect2, varscan2
- PRDM13 | c.1074G>A p.A358= | Silent (SNP) | VAF 312/760 reads (41%) | called by muse, varscan2
- RBM10 | c.1731C>G p.T577= | Silent (SNP) | VAF 180/530 reads (34%) | catalogued as rs1556780031; called by muse, mutect2, varscan2
- SETD7 | c.966G>A p.L322= | Silent (SNP) | VAF 29/512 reads (6%) | called by muse, mutect2
- TUBB2B | c.1227C>T p.T409= | Silent (SNP) | VAF 132/530 reads (25%) | catalogued as rs751743160, COSV52533785; called by muse, mutect2, varscan2
- WWC2 | c.294G>A p.K98= | Silent (SNP) | VAF 169/501 reads (34%) | catalogued as rs1163319367; called by muse, mutect2, varscan2
